Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4817, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4817-01A (Primary Tumor).

FINAL DIAGNOSIS

TCGA-B0-4817

PART 1: KIDNEY, RIGHT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (clear cell) TYPE, 4.8 CM, FUHRMAN'S NUCLEAR GRADE 2-3/4 (see comment).
- B. TUMOR EXTENDS INTO PERIRENAL ADIPOSE TISSUE AND RENAL SINUS, BUT DOES NOT INVOLVE GEROTA'S FASCIA (sections 1B, 1H, 1I).
- C. RENAL CELL CARCINOMA THROMBUS IS PRESENT IN AND OCCLUDES A LARGE RENAL VEIN (slide 1H).
- D. URETER, VASCULAR AND PERIRENAL SOFT TISSUE RESECTION MARGINS FREE OF TUMOR.
- E. NON-NEOPLASTIC KIDNEY WITH ARTERIAL / ARTERIOLAR NEPHROSCLEROSIS, WITH FOCAL GLOBAL GLOMERULOSCLEROSIS INVOLVING APPROXIMATELY 15% OF GLOMERULI, AND ONLY MILD TUBULOINTERSTITIAL CHRONIC CHANGES.
- F. PATHOLOGIC STAGE: T3c; NX; MX.

PART 2: ADRENAL, RIGHT, ADRENALECTOMY -

BENIGN ADRENAL GLAND. NO EVIDENCE OF MALIGNANCY.

PART 3: THROMBUS, INFERIOR VENA CAVA, THROMBECTOMY -

THROMBUS COMPRISED OF METASTATIC RENAL CELL CARCINOMA SIMILAR TO RENAL PRIMARY.

COMMENT:

The Fuhrman nuclear grade in most of the carcinoma is 2/4, but focally is 3/4.

Source: NCI Genomic Data Commons file 01dd6fc9-9d43-48b0-bc54-421bddb3ff9c (TCGA-B0-4817.85BE41D7-EC54-4CDE-ABE1-5400FE3AE2A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).